Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7603, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7603-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Microscopic Description:

Sections demonstrate a mildly to moderately hypercellular glial neoplasm, the cells of which resemble mildly atypical oligodendrocytes. No mitotic figures are seen. There is no microvascular proliferation or necrosis. The tumor infiltrates both gray and white matter diffusely.

Addendum Discussion:

MIB-1 cells are present in vague clusters throughout the tumor. In the most proliferative areas, a labeling index of 2.3% is calculated, indicative of a modestly proliferative tumor.

Addendum Diagnosis:

Low Grade Oligodendroglioma, WHO Grade II
MIB-1 Labeling Index= 2.3%

Source: NCI Genomic Data Commons file 351291aa-c552-4d8e-a805-2d7a99ea3b7d (TCGA-HT-7603.1BAE23F1-0F8D-4DCC-B47D-AFB522675E88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).